Somatic mutation profile of tumor specimen TCGA-C5-A0TN-01A (aliquot TCGA-C5-A0TN-01A-21D-A14W-08) from TCGA case TCGA-C5-A0TN, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 21.2 years (7,760 days).
Specimen TCGA-C5-A0TN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0be2d54c-a35f-4a44-aafa-d1c1eeb560c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A0TN-10B (Blood Derived Normal), aliquot TCGA-C5-A0TN-10B-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f4c388c-8070-46cc-a9d2-eca0ebe10e60

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 16, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.6327-1G>A p.X2109_splice | Splice Site (SNP) | VAF 23/35 reads (66%) | catalogued as COSV64872617, COSV64885865; called by muse, mutect2, varscan2
- CEP250 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775018359, COSV61175488; called by muse, mutect2, varscan2
- CGN | c.3277C>T p.R1093W | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761934907, COSV54974672; called by muse, mutect2, varscan2
- GLI2 | c.2234C>T p.P745L (on ENST00000361492 / NM_001374353.1; = p.P762L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.318); catalogued as rs369835105, COSV100082903; called by muse, mutect2, varscan2
- HPCAL1 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 84/209 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57150016; called by muse, mutect2, varscan2
- LRFN1 | c.746T>G p.F249C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50517666; called by muse, mutect2, varscan2
- MRPL3 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 117/265 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV53916689; called by muse, mutect2, varscan2
- ROBO1 | c.318G>C p.E106D | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV71399412; called by muse, mutect2, varscan2
- SGSM1 | c.3404G>A p.R1135Q (on ENST00000400359 / NM_001039948.4; = p.R1074Q on NM_133454.3) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV68514425; called by muse, mutect2, varscan2
- SNTG2 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.112); catalogued as COSV100422606, COSV100423571, COSV58011512; called by muse, mutect2
- TAF7L | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 126/273 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs145455495, COSV61256962; called by muse, mutect2, varscan2
- TRA2A | c.524A>G p.E175G | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV51719405; called by muse, varscan2
- WDR17 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 43/46 reads (93%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); catalogued as rs777480260, COSV54578454; called by muse, mutect2, varscan2
- WDR49 | c.2041G>T p.A681S (on ENST00000308378 / NM_001366158.1; = p.A1022S on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as COSV52989628; called by muse, mutect2, varscan2
- ZFHX4 | c.7118C>T p.A2373V | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV51503349; called by muse, mutect2, varscan2
- ZNF334 | c.1391A>G p.N464S | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs866061552, COSV61620561; called by muse, mutect2, varscan2
- ZNF404 | c.330G>A p.M110I | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as COSV60989338; called by muse, mutect2
- PDZRN4 | c.258C>T p.R86= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs754990542, COSV68419066; called by muse, mutect2, varscan2
- UNG | c.408C>T p.T136= (on ENST00000242576 / NM_080911.3; = p.T127= on NM_003362.4) | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as COSV54359229; called by muse, mutect2, varscan2
